Somatic mutation profile of tumor specimen TCGA-75-6211-01A (aliquot TCGA-75-6211-01A-11D-1753-08) from TCGA case TCGA-75-6211, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB.
Specimen TCGA-75-6211-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc65e332-d7be-47f1-9fa0-b9933bc8873e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-75-6211-10A (Blood Derived Normal), aliquot TCGA-75-6211-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a79de6c-d4e3-4ca5-b862-8800f01d9116

The open-access MAF lists 403 somatic variants for this specimen: 311 protein-altering or splice-affecting, 77 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 266, Silent 77, Nonsense Mutation 25, Frame Shift Del 7, Intron 6, Frame Shift Ins 4, Splice Site 4, RNA 4, 3'Flank 3, Nonstop Mutation 3, Splice Region 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.2681G>C p.G894A | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs587779589, CM022338, CM1412638, COSV58591385; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GDF2 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199804679, CM138625; ClinVar: pathogenic; called by muse, mutect2
- MAP2K1 | c.157T>C p.F53L | Missense Mutation (SNP) | VAF 49/163 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as rs1057519728, COSV61068605, COSV61070825, COSV61071840; ClinVar: pathogenic; called by muse, mutect2, varscan2
- N4BP2L2 | c.2738dup p.N913Kfs*2 (on ENST00000674422; = p.N484Kfs*2 on NM_033111.4) | Frame Shift Ins (INS) | VAF 5/32 reads (16%) | catalogued as rs1158061584; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACAD10 | c.2533G>T p.D845Y | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58158918; called by muse, mutect2, varscan2
- ACAN | c.1823C>A p.T608K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV61363340; called by muse, mutect2, varscan2
- ADAMTS18 | c.2111G>T p.G704V | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1400467834, COSV51418061; called by muse, mutect2
- ADCY6 | c.1304G>T p.G435V | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100326446; called by muse, mutect2, varscan2
- ADCY6 | c.1303G>T p.G435W | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100326451; called by muse, mutect2, varscan2
- ADGRF4 | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV51953888; called by muse, mutect2, varscan2
- ADGRG4 | c.5414C>T p.T1805I | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV54960343; called by muse, mutect2, varscan2
- ADGRL4 | c.1625C>A p.A542D | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66060944, COSV66062603; called by muse, mutect2, varscan2
- AGBL2 | c.467T>A p.V156E | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV54093308; called by muse, mutect2, varscan2
- AGO3 | c.1828C>A p.P610T | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55794590; called by muse, mutect2, varscan2
- AHNAK2 | c.11502G>T p.E3834D | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.04); catalogued as COSV60920023; called by muse, mutect2, varscan2
- AIFM1 | c.117C>A p.F39L | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54855817; called by muse, mutect2, varscan2
- AIPL1 | c.578G>T p.R193L | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.889); catalogued as COSV51507625, COSV51508509; called by muse, mutect2, varscan2
- ANGEL1 | c.327G>T p.W109C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.808); catalogued as COSV99200337; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1189A>C p.I397L | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV62005875; called by muse, mutect2
- ANO2 | c.2820C>A p.S940R (on ENST00000356134 / NM_001278597.3; = p.S944R on NM_001278596.3) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV59030119; called by muse, mutect2, varscan2
- APEX2 | c.1342G>T p.E448* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100238082; called by muse, mutect2, varscan2
- APOA4 | c.425T>A p.L142Q | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63360656; called by muse, mutect2, varscan2
- ARHGEF11 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.021); catalogued as COSV63813748; called by muse, mutect2, varscan2
- ASTN2 | c.2027C>A p.S676Y (on ENST00000313400 / NM_001365069.1; = p.S625Y on NM_014010.5) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57761542, COSV57791174; called by muse, mutect2, varscan2
- ATP7A | c.2692G>T p.G898W | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58448727; called by muse, mutect2, varscan2
- ATRX | c.3857C>A p.S1286Y | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV64878940; called by muse, mutect2, varscan2
- BCAS2 | c.59A>G p.D20G | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1277979341, COSV65767504; called by muse, mutect2, varscan2
- BEND2 | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV66221144; called by muse, mutect2, varscan2
- BRCA2 | c.8084C>A p.S2695* | Nonsense Mutation (SNP) | VAF 17/109 reads (16%) | catalogued as CM119496, COSV66456629; called by muse, mutect2, varscan2
- BRI3BP | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as rs201462094, COSV58296546; called by muse, mutect2, varscan2
- BTK | c.589A>G p.I197V | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV58121308; called by muse, mutect2, varscan2
- BTK | c.434G>C p.C145S | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.627); catalogued as COSV58121319; called by muse, mutect2, varscan2
- BTK | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV58117893, COSV58121329; called by muse, mutect2, varscan2
- BTN3A3 | c.938-2A>T p.X313_splice | Splice Site (SNP) | VAF 37/149 reads (25%) | catalogued as COSV55072586; called by muse, mutect2, varscan2
- C5orf58 | c.234T>A p.S78R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV50453534; called by muse, mutect2, varscan2
- CACHD1 | c.3592A>T p.S1198C | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51555807; called by muse, mutect2, varscan2
- CACNA1E | c.4102G>A p.V1368I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as rs574530214, COSV62402477; called by muse, mutect2, varscan2
- CAND1 | c.781G>T p.V261L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.184); catalogued as COSV73338616; called by muse, mutect2, varscan2
- CAP2 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 28/108 reads (26%) | catalogued as COSV57733869; called by muse, mutect2, varscan2
- CBFA2T3 | c.916C>A p.R306S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV51927458, COSV51929167; called by muse, mutect2, varscan2
- CCDC148 | c.545A>G p.Q182R | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.219); catalogued as COSV51764476; called by muse, mutect2, varscan2
- CCDC158 | c.1549G>T p.A517S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV66356489; called by muse, mutect2, varscan2
- CCDC171 | c.3139C>T p.L1047F | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.865); catalogued as COSV52645082; called by muse, mutect2, varscan2
- CCDC178 | c.1872A>T p.K624N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.625); catalogued as COSV55781266; called by muse, mutect2, varscan2
- CCDC7 | c.3606G>T p.E1202D | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.137); catalogued as rs144109242, COSV56537241, COSV56545405; called by muse, mutect2
- CD5L | c.179T>C p.V60A | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63822393; called by muse, mutect2, varscan2
- CDK13 | c.3172A>G p.T1058A | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV51702512; called by muse, mutect2
- CDKL5 | c.1538C>T p.T513I | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); catalogued as COSV66111956; called by muse, mutect2, varscan2
- CEP192 | c.2640G>T p.K880N | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV58066644; called by muse, mutect2, varscan2
- CFAP206 | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99739249; called by muse, mutect2, varscan2
- CFAP47 | c.5157C>A p.Y1719* | Nonsense Mutation (SNP) | VAF 37/142 reads (26%) | catalogued as COSV57974835; called by muse, mutect2, varscan2
- CFAP70 | c.3157G>T p.E1053* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV60284384; called by muse, mutect2, varscan2
- CFC1 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.218); catalogued as COSV52090625; called by muse, mutect2, varscan2
- CHD5 | c.2976C>A p.C992* | Nonsense Mutation (SNP) | VAF 20/150 reads (13%) | catalogued as COSV52410753, COSV52418292; called by muse, mutect2, varscan2
- CHD9 | c.6785G>T p.R2262L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54612256; called by mutect2, varscan2
- CHFR | c.1870G>C p.E624Q (on ENST00000432561 / NM_001161345.1; = p.E583Q on NM_018223.2) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as rs777155485, COSV57175699; called by muse, mutect2, varscan2
- CHRND | c.55A>T p.S19C | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV51323030; called by muse, mutect2, varscan2
- CHST7 | c.579C>A p.F193L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99332810; called by muse, mutect2, varscan2
- CKAP2 | c.1100G>C p.R367T (on ENST00000378037 / NM_001098525.2; = p.R366T on NM_018204.5) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV51622986; called by muse, mutect2, varscan2
- CLCA1 | c.1303G>A p.V435I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.268); catalogued as COSV52328826; called by muse, mutect2
- CNBD1 | c.650T>G p.L217R | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV101575276; called by muse, mutect2, varscan2
- CNGA3 | c.918G>C p.L306F | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV55625450; called by muse, mutect2, varscan2
- CNTNAP5 | c.918G>T p.E306D | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70493673; called by muse, mutect2, varscan2
- COL10A1 | c.1987T>C p.Y663H | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV54573502; called by muse, mutect2, varscan2
- COL14A1 | c.2499G>T p.Q833H | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV52859115; called by muse, mutect2, varscan2
- COL19A1 | c.2750G>T p.G917V | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59577443; called by muse, mutect2, varscan2
- COL3A1 | c.4300C>A p.R1434S | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.23); catalogued as COSV58586131, COSV58591395; called by muse, mutect2, varscan2
- COPS2 | c.740G>C p.R247T | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as COSV100157302, COSV54645946; called by muse, mutect2, varscan2
- CRP | c.449G>T p.S150I | Missense Mutation (SNP) | VAF 91/425 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.46); catalogued as COSV54813947; called by muse, mutect2, varscan2
- CSGALNACT1 | c.852-1G>C p.X284_splice | Splice Site (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100175507, COSV59979526; called by muse, mutect2, varscan2
- CSMD2 | c.5G>A p.R2K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV53927026; called by muse, mutect2, varscan2
- CSMD3 | c.10720A>T p.N3574Y (on ENST00000297405 / NM_001363185.1; = p.N3405Y on NM_052900.3) | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV52225366, COSV52269630; called by muse, mutect2
- CSPG4 | c.1779G>C p.Q593H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV57897442, COSV57903409; called by muse, mutect2, varscan2
- CUBN | c.7499C>A p.A2500D | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV64710151, COSV64719710; called by muse, mutect2, varscan2
- CUX2 | c.4019G>T p.G1340V | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.013); catalogued as rs375555910, COSV55637603; called by muse, mutect2, varscan2
- CYBB | c.1275del p.Y425* | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | catalogued as CM015930; called by mutect2, pindel, varscan2
- CYP19A1 | c.891C>A p.N297K | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.46); catalogued as COSV53060341; called by muse, mutect2, varscan2
- CYP4A11 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 65/382 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs556756716, COSV60224205; called by muse, mutect2, varscan2
- DENND1B | c.407A>T p.H136L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV52467677; called by muse, mutect2, varscan2
- DENND2C | c.377G>T p.S126I | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV67922436; called by muse, mutect2, varscan2
- DMXL2 | c.7817C>T p.S2606F | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV51849536; called by muse, mutect2, varscan2
- DOCK4 | c.5671G>T p.E1891* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV70239356; called by muse, mutect2
- DRC1 | c.573G>T p.K191N | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56532684; called by muse, mutect2, varscan2
- DSG4 | c.1038G>T p.Q346H | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV57393534; called by muse, mutect2, varscan2
- DYNC1H1 | c.1344G>T p.M448I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as COSV100794622; called by muse, mutect2
- ECD | c.1138A>T p.M380L | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV65900363; called by muse, mutect2, varscan2
- ECE2 | c.59C>G p.A20G | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.342); catalogued as rs1201769010, COSV100668459; called by muse, varscan2
- EGLN3 | c.615-1G>T p.X205_splice | Splice Site (SNP) | VAF 7/63 reads (11%) | catalogued as COSV51655351; called by muse, mutect2, varscan2
- EMC1 | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV61887021; called by muse, mutect2, varscan2
- EPX | c.1577C>A p.P526H | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.98); catalogued as COSV99836325; called by muse, mutect2, varscan2
- ESYT2 | c.2293G>T p.A765S (on ENST00000613624; = p.A689S on NM_020728.3) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.544); catalogued as COSV51752843, COSV99277101; called by muse, mutect2, varscan2
- FABP9 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.29); catalogued as rs749835352, COSV66911575; called by muse, mutect2, varscan2
- FAM160A2 | c.2302G>T p.A768S (on ENST00000449352 / NM_001098794.2; = p.A782S on NM_032127.4) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV56412476; called by muse, mutect2, varscan2
- FAM160B1 | c.1762G>T p.G588C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV65088622; called by muse, mutect2, varscan2
- FAT3 | c.3747C>A p.D1249E | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53133172; called by muse, mutect2
- FBN2 | c.5673A>G p.V1891= | Splice Region (SNP) | VAF 16/45 reads (36%) | catalogued as COSV52524188; called by muse, mutect2, varscan2
- FBXW8 | c.897G>T p.Q299H (on ENST00000309909; = p.Q337H on NM_012174.1) | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV59301095; called by muse, mutect2, varscan2
- FCAR | c.811C>A p.Q271K | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as COSV62030281; called by muse, mutect2, varscan2
- FIZ1 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs758897035, COSV55608233; called by muse, mutect2, varscan2
- FLG | c.4594C>A p.H1532N | Missense Mutation (SNP) | VAF 123/513 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100910960; called by muse, mutect2, varscan2
- FRMPD3 | c.2305C>G p.L769V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99345826; called by muse, mutect2
- FSIP2 | c.19552C>A p.P6518T | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100554389; called by muse, mutect2
- FZD7 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99636945; called by muse, mutect2, varscan2
- GABRB3 | c.713G>T p.R238L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV54671048, COSV54673017; called by muse, mutect2, varscan2
- GALNT17 | c.1451T>A p.L484Q | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.027); catalogued as COSV61169738; called by muse, mutect2
- GGH | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV52650922; called by mutect2, varscan2
- GHR | c.1223C>T p.T408I | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.299); catalogued as rs1306929778, COSV50117757; called by muse, mutect2, varscan2
- GLS2 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.031); catalogued as COSV57665679; called by muse, mutect2, varscan2
- GPR148 | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV59308652, COSV59309236; called by muse, mutect2, varscan2
- GREM2 | c.161C>A p.A54D | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV100547353; called by muse, mutect2, varscan2
- GRIA3 | c.2648G>A p.G883D | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52068251; called by muse, mutect2, varscan2
- GRID1 | c.1998G>T p.R666S | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV100022521; called by muse, mutect2, varscan2
- GRID1 | c.1998-1G>T p.X666_splice | Splice Site (SNP) | VAF 17/125 reads (14%) | catalogued as COSV100022525; called by muse, mutect2, varscan2
- GRIK3 | c.2267T>C p.I756T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV66142037; called by muse, mutect2, varscan2
- GRIP2 | c.2068G>T p.V690L (on ENST00000619221; = p.V593L on NM_001080423.4) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV56122537; called by muse, mutect2, varscan2
- HCFC2 | c.1870A>T p.I624F | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV57559026; called by muse, mutect2, varscan2
- HEATR1 | c.2468G>T p.R823M | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.641); catalogued as COSV63981827; called by muse, mutect2, varscan2
- HEPHL1 | c.3030G>T p.E1010D | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); catalogued as COSV59893469; called by muse, mutect2, varscan2
- HERC2 | c.9319G>T p.G3107W | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55331449; called by muse, mutect2, varscan2
- HIF3A | c.1153G>T p.G385C (on ENST00000377670 / NM_152795.4; = p.G316C on NM_022462.4) | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV52200330; called by muse, mutect2, varscan2
- HMCN1 | c.16861C>A p.Q5621K | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV54913198; called by muse, mutect2, varscan2
- HMGCLL1 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs1326343067, COSV51447149, COSV99232481; called by muse, mutect2, varscan2
- HMGCR | c.1889G>T p.R630L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99843078; called by muse, mutect2, varscan2
- HPSE2 | c.218C>G p.T73R | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.276); catalogued as COSV65192969; called by muse, mutect2, varscan2
- HRC | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.831); catalogued as rs764751124, COSV53257219; called by muse, mutect2, varscan2
- IFT46 | c.354G>C p.K118N (on ENST00000264021 / NM_001168618.2; = p.K169N on NM_020153.3) | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50594584; called by muse, mutect2, varscan2
- IGF2R | c.5341A>T p.S1781C | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV63630313; called by muse, mutect2
- INPP4A | c.2461G>T p.V821F (on ENST00000074304 / NM_001134224.1; = p.V782F on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.203); catalogued as COSV50800203; called by muse, mutect2, varscan2
- ISM2 | c.1640A>T p.N547I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs969461361, COSV53635759; called by muse, mutect2, varscan2
- ITGAL | c.2027A>T p.Q676L | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as COSV63322935; called by muse, mutect2, varscan2
- ITPK1 | c.910G>T p.G304C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50896786; called by muse, mutect2, varscan2
- ITPKC | c.1377G>T p.M459I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54575684; called by muse, mutect2, varscan2
- KCNB2 | c.2629G>T p.D877Y | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.345); catalogued as COSV73051129, COSV73052870; called by muse, mutect2, varscan2
- KCNH2 | c.1322C>A p.P441H | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV51199498; called by muse, mutect2, varscan2
- KCNJ2 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as rs895505794, COSV54660976; called by muse, mutect2
- KCNJ3 | c.1379C>A p.S460Y | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); catalogued as COSV54538795, COSV54544877; called by muse, varscan2
- KCNT1 | c.2659C>T p.Q887* (on ENST00000488444; = p.Q906* on NM_020822.3) | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV53704415; called by muse, mutect2, varscan2
- KCNU1 | c.1403C>A p.T468N | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV67757427; called by muse, mutect2, varscan2
- KEAP1 | c.611G>C p.R204P | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV50308555; called by muse, varscan2
- KRT81 | c.9C>A p.C3* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as rs1191423555, COSV100576940, COSV59810546; called by muse, mutect2, varscan2
- KRTAP3-3 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs768805721, COSV66956765; called by muse, mutect2, varscan2
- LAMP2 | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 57/382 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as CM123562, COSV99568271; called by muse, mutect2, varscan2
- LCE2C | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.009); catalogued as COSV100909401; called by muse, mutect2, varscan2
- LCK | c.573C>G p.F191L | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV60741228; called by muse, mutect2, varscan2
- LGR6 | c.532C>A p.P178T (on ENST00000367278 / NM_001017403.1; = p.P126T on NM_021636.3) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55160100; called by muse, mutect2, varscan2
- LRP2 | c.1017C>A p.N339K | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs749358826, COSV55560003; called by muse, mutect2, varscan2
- LYPD6 | c.514T>C p.*172Qext*8 | Nonstop Mutation (SNP) | VAF 29/112 reads (26%) | catalogued as COSV61941003; called by muse, mutect2, varscan2
- MAGEB1 | c.330G>T p.W110C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV100974881; called by muse, mutect2, varscan2
- MAGEB2 | c.354G>T p.L118F | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100975607; called by muse, mutect2
- MAGT1 | c.656G>T p.W219L (on ENST00000618282 / NM_001367916.1; = p.W251L on NM_032121.5) | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63782239; called by muse, mutect2, varscan2
- MEI1 | c.2739C>G p.S913R | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.224); catalogued as COSV55904443; called by muse, mutect2
- MERTK | c.1604G>T p.G535V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54931595; called by muse, mutect2, varscan2
- MOGAT2 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99549406; called by muse, mutect2, varscan2
- MOGAT2 | c.326C>A p.P109H | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99549412; called by muse, mutect2, varscan2
- MS4A14 | c.1822G>C p.D608H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV55735974; called by muse, mutect2, varscan2
- MSLN | c.1284G>T p.K428N (on ENST00000382862 / NM_013404.4; = p.K420N on NM_005823.6) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.072); catalogued as COSV53503581; called by muse, mutect2, varscan2
- MTHFSD | c.280G>T p.G94* (on ENST00000360900 / NM_001159377.2; = p.G93* on NM_022764.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 29/130 reads (22%) | catalogued as COSV59803848; called by muse, mutect2, varscan2
- MTO1 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 26/69 reads (38%) | catalogued as COSV64774148; called by muse, mutect2, varscan2
- MUC16 | c.37045C>A p.H12349N | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.139); catalogued as COSV67476045; called by muse, mutect2, varscan2
- MUC16 | c.28252G>T p.D9418Y | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as COSV67476046; called by muse, mutect2, varscan2
- MYH2 | c.769A>T p.T257S | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV55441342; called by muse, mutect2, varscan2
- MYH2 | c.584A>G p.Y195C | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55441350; called by muse, mutect2, varscan2
- MYH3 | c.4978G>C p.D1660H | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV56866763; called by muse, mutect2, varscan2
- NACA2 | c.17C>A p.T6K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.188); catalogued as COSV71713150; called by muse, mutect2, varscan2
- NCAM2 | c.2071A>G p.I691V | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV53084724; called by muse, mutect2, varscan2
- NEDD1 | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV57144410; called by muse, mutect2
- NEK1 | c.2356A>T p.T786S | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV71456637; called by muse, mutect2, varscan2
- NELL1 | c.1683C>G p.H561Q | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.288); catalogued as COSV54283496; called by muse, mutect2, varscan2
- NF1 | c.6101C>T p.T2034I (on ENST00000358273 / NM_001042492.3; = p.T2013I on NM_000267.3) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1567616695, COSV62208622; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFKBID | c.812G>T p.G271V (on ENST00000396901; = p.G423V on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61729222; called by muse, mutect2, varscan2
- NIPA1 | c.835C>G p.L279V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61680185; called by muse, mutect2
- NKD1 | c.208G>T p.V70L | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.045); catalogued as COSV51692199; called by muse, mutect2, varscan2
- NLRP6 | c.2392C>T p.Q798* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as rs1243569298, COSV56460548; called by muse, mutect2, varscan2
- NPC1L1 | c.3005G>T p.R1002M | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56926695; called by muse, mutect2, varscan2
- NUP107 | c.219G>T p.Q73H | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV57495687; called by muse, mutect2, varscan2
- OAS2 | c.899A>T p.N300I | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV60803193; called by muse, mutect2, varscan2
- OCA2 | c.1900A>T p.I634F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV62349700; called by muse, mutect2, varscan2
- OR10C1 | c.409C>A p.L137M (on ENST00000622521; = p.L135M on NM_013941.3) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV65823357; called by muse, mutect2
- OR10R2 | c.704G>T p.C235F | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV63769039; called by muse, mutect2, varscan2
- OR10S1 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.824); catalogued as rs761498954, COSV73342876; called by muse, mutect2, varscan2
- OR13H1 | c.871C>A p.L291M | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100088317, COSV58547834; called by muse, mutect2, varscan2
- OR1C1 | c.56G>T p.S19I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.536); catalogued as COSV68715922; called by muse, mutect2, varscan2
- OR2B11 | c.938G>T p.W313L | Missense Mutation (SNP) | VAF 108/447 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV59510589; called by muse, mutect2, varscan2
- OR2H1 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 14/116 reads (12%) | catalogued as COSV65810923; called by muse, mutect2, varscan2
- OR4A47 | c.687A>T p.K229N | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as COSV71445009, COSV71445037; called by muse, mutect2, varscan2
- OR56A1 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV57363051; called by muse, mutect2, varscan2
- OR8J1 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 14/139 reads (10%) | catalogued as COSV57318924, COSV57320064; called by muse, mutect2, varscan2
- OR9I1 | c.233C>A p.T78N | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs766627351, COSV56926778; called by muse, mutect2, varscan2
- OSBPL7 | c.1907A>T p.K636M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50110639; called by muse, mutect2, varscan2
- PAPPA | c.3074C>A p.S1025Y | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV60286608, COSV60289509; called by muse, mutect2, varscan2
- PAPPA2 | c.1433T>A p.L478H | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.474); catalogued as COSV62780823; called by muse, mutect2, varscan2
- PATE1 | c.330G>T p.L110F | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs745523166; called by muse, mutect2
- PCDH7 | c.1451A>C p.K484T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62336171, COSV62340480; called by mutect2, varscan2
- PCDH8 | c.3106C>A p.P1036T | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV58813529; called by muse, mutect2, varscan2
- PCDHA2 | c.466G>T p.G156* | Nonsense Mutation (SNP) | VAF 29/63 reads (46%) | catalogued as COSV65368267, COSV65368582; called by muse, mutect2, varscan2
- PCDHB12 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.1); catalogued as COSV53398121; called by muse, mutect2, varscan2
- PCDHB2 | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV99522914; called by muse, mutect2, varscan2
- PCDHGA6 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs975173370, COSV53975807, COSV54043909; called by muse, mutect2, varscan2
- PKD1L2 | c.1351T>A p.S451T | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV61416681; called by muse, mutect2, varscan2
- PKD2 | c.995C>G p.S332C | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs763064353, COSV52939270; called by muse, mutect2, varscan2
- PKHD1L1 | c.8749G>A p.G2917R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as rs1409644882, COSV65746310; called by muse, mutect2
- PLA2G4C | c.22A>T p.I8L | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.217); catalogued as COSV62786215; called by muse, mutect2, varscan2
- PM20D2 | c.1100A>G p.Y367C | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.225); catalogued as rs935714655, COSV51531151; called by muse, mutect2, varscan2
- PMFBP1 | c.1660G>T p.V554L (on ENST00000537465; = p.V549L on NM_031293.3) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs769856820, COSV99400401; called by muse, mutect2, varscan2
- POLM | c.560A>G p.K187R | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.146); catalogued as rs754904576, COSV54243091; called by muse, mutect2, varscan2
- POLR1B | c.1402C>T p.H468Y | Missense Mutation (SNP) | VAF 77/277 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54500111; called by muse, mutect2, varscan2
- PPARA | c.510G>A p.A170= | Splice Region (SNP) | VAF 10/69 reads (14%) | catalogued as rs571736420, COSV53078529; called by muse, mutect2, varscan2
- PPDPFL | c.220C>A p.L74M | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV100293053, COSV57460830; called by muse, mutect2, varscan2
- PRKX | c.262C>A p.L88I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV99467772; called by mutect2, varscan2
- PTGIR | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52192571, COSV52192634; called by muse, mutect2, varscan2
- PTPN12 | c.2033C>T p.P678L | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767180759, COSV50356620, COSV50362976; called by muse, mutect2, varscan2
- PXDN | c.2542A>T p.S848C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV53238779; called by muse, mutect2, varscan2
- PZP | c.2293C>A p.P765T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54355439, COSV54363756; called by muse, mutect2, varscan2
- QRICH2 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as rs536269106, COSV53154644; called by muse, mutect2, varscan2
- RASAL1 | c.1069C>T p.L357F | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as COSV55657408; called by muse, mutect2
- RBM46 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55980056; called by muse, mutect2, varscan2
- RERGL | c.570G>T p.M190I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.035); catalogued as COSV99967812; called by muse, mutect2, varscan2
- RGS1 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 31/97 reads (32%) | catalogued as COSV66505690; called by muse, mutect2, varscan2
- RIOK1 | c.87G>T p.L29F | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.083); catalogued as COSV53572393, COSV53573070; called by muse, mutect2, varscan2
- RMDN1 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52204302, COSV52207643; called by muse, mutect2, varscan2
- ROBO4 | c.2758G>A p.G920S | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs529793135, COSV60625486; called by muse, mutect2, varscan2
- RP1 | c.1003A>T p.M335L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55119960; called by muse, mutect2, varscan2
- RTL3 | c.1290C>A p.H430Q | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.22); catalogued as COSV100330178, COSV58184622; called by muse, mutect2, varscan2
- RTL4 | c.446A>T p.N149I | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.876); catalogued as COSV61206765; called by muse, mutect2, varscan2
- SAMD7 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59419632; called by muse, mutect2, varscan2
- SCAPER | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs771125619, COSV57739669, COSV57740127; called by muse, mutect2, varscan2
- SCLT1 | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV99827717; called by muse, mutect2, varscan2
- SCML2 | c.1946G>A p.G649D | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV99318695; called by muse, mutect2, varscan2
- SCN1A | c.2176G>T p.E726* (on ENST00000303395 / NM_001202435.3; = p.E715* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 33/122 reads (27%) | catalogued as rs1553543824, COSV57675557; called by muse, mutect2, varscan2
- SENP6 | c.2152C>G p.L718V | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64188323; called by muse, mutect2, varscan2
- SF3B3 | c.3652T>C p.*1218Rext*35 | Nonstop Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100209658; called by muse, mutect2, varscan2
- SF3B3 | c.3653G>T p.*1218Lext*35 | Nonstop Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100209669; called by muse, mutect2, varscan2
- SLC17A8 | c.1045A>G p.I349V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.163); catalogued as COSV60124831; called by muse, mutect2, varscan2
- SLC34A1 | c.971C>A p.S324Y | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60997484; called by muse, mutect2
- SLC38A8 | c.1009G>T p.A337S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.392); catalogued as COSV55307755, COSV55308715; called by muse, mutect2, varscan2
- SLC38A8 | c.932C>G p.P311R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765635340, COSV55306451, COSV55307764; called by muse, mutect2
- SLC5A5 | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV55833849; called by muse, mutect2, varscan2
- SLC6A16 | c.1265G>T p.G422V | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV60028612; called by muse, mutect2, varscan2
- SLC7A9 | c.847C>T p.L283F | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.807); catalogued as rs1357600282, CM050101, COSV50087424; called by muse, mutect2
- SLCO1B3 | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53940546; called by muse, mutect2
- SMG9 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV54215227; called by muse, mutect2
- SNIP1 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV56167155; called by muse, mutect2, varscan2
- SOX17 | c.212C>A p.P71Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52025847, COSV52026590; called by muse, mutect2, varscan2
- SPIN3 | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100888458; called by muse, mutect2
- SPTB | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV67632957; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2707A>G p.I903V | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763386660, COSV59132777; called by muse, mutect2, varscan2
- SWT1 | c.2237T>C p.L746P | Missense Mutation (SNP) | VAF 34/307 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV62256529; called by muse, mutect2, varscan2
- SYT6 | c.841C>A p.L281M (on ENST00000610222 / NM_001366225.1; = p.L196M on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV101059617; called by muse, mutect2, varscan2
- TASOR2 | c.1724C>A p.S575Y | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV60167351; called by muse, mutect2, varscan2
- TDRD1 | c.1673G>A p.W558* | Nonsense Mutation (SNP) | VAF 20/152 reads (13%) | catalogued as COSV52592278; called by muse, mutect2, varscan2
- TENM1 | c.4156A>T p.I1386F | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV64435675; called by muse, mutect2, varscan2
- TEX15 | c.887G>A p.C296Y (on ENST00000256246; = p.C679Y on NM_001350162.2) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV56348571; called by muse, mutect2, varscan2
- TFAP2D | c.346C>A p.L116M | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV50429208; called by muse, mutect2, varscan2
- TIAM2 | c.1282G>T p.A428S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV59693228, COSV59697009; called by muse, mutect2, varscan2
- TLL2 | c.413C>A p.A138D | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.069); catalogued as rs764664323, COSV100780182; called by muse, mutect2, varscan2
- TLR4 | c.2042C>A p.S681* (on ENST00000355622 / NM_138554.5; = p.S641* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 25/70 reads (36%) | catalogued as COSV62923655, COSV62924232; called by muse, mutect2, varscan2
- TMEM209 | c.208C>T p.L70F | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as rs1311511555, COSV61022882; called by muse, mutect2, varscan2
- TMEM67 | c.1841G>C p.G614A | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV60039591, COSV60041310; called by muse, mutect2, varscan2
- TMTC4 | c.44C>G p.S15C (on ENST00000376234 / NM_001350577.2; = p.S34C on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1308374715, COSV60892697; called by muse, mutect2, varscan2
- TMX4 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV55681205; called by muse, mutect2
- TNR | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54895567; called by muse, mutect2, varscan2
- TPTE | c.484G>T p.D162Y (on ENST00000618007 / NM_199261.4; = p.D144Y on NM_199259.4) | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs779972291; called by muse, mutect2
- TRPC4 | c.692G>T p.S231I | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59005494; called by muse, mutect2, varscan2
- TSC1 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as rs118203392, CM090913, COSV53768882; ClinVar: not provided; called by muse, mutect2, varscan2
- TTC21A | c.2603G>T p.R868L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as COSV57185265, COSV57186418; called by muse, mutect2, varscan2
- TTN | c.53371C>A p.R17791S (on ENST00000591111; = p.R10367S on NM_003319.4) | Missense Mutation (SNP) | VAF 27/107 reads (25%) | PolyPhen benign (0.14); catalogued as COSV60158018, COSV60280432; called by muse, mutect2, varscan2
- TTN | c.50351G>A p.G16784E (on ENST00000591111; = p.G9360E on NM_003319.4) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | PolyPhen benign (0.011); catalogued as COSV60158064; called by muse, mutect2, varscan2
- TULP3 | c.633G>T p.R211S | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV68118209; called by muse, mutect2, varscan2
- U2AF2 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV58274582; called by muse, mutect2, varscan2
- USH2A | c.4219C>A p.P1407T | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV56391710; called by muse, mutect2, varscan2
- USP29 | c.2593T>A p.S865T | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.448); catalogued as COSV54144111; called by muse, mutect2, varscan2
- USP43 | c.832A>T p.R278W | Missense Mutation (SNP) | VAF 85/186 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53304227; called by muse, mutect2, varscan2
- USP6NL | c.1472C>A p.S491* | Nonsense Mutation (SNP) | VAF 26/192 reads (14%) | catalogued as COSV53212928; called by muse, mutect2, varscan2
- VWA3B | c.2913G>T p.L971F | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV68244167; called by muse, mutect2, varscan2
- VWF | c.987C>A p.C329* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV54625388; called by muse, mutect2, varscan2
- WARS1 | c.1250G>T p.R417M | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs772254998, COSV59926171; called by muse, mutect2, varscan2
- WDR44 | c.286A>C p.S96R | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV54165299; called by muse, mutect2, varscan2
- WDR49 | c.1328G>T p.W443L (on ENST00000308378 / NM_001366158.1; = p.W784L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV57711299; called by muse, mutect2, varscan2
- WIPF1 | c.652A>T p.T218S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV55816508; called by muse, mutect2, varscan2
- ZFP30 | c.1399G>T p.D467Y | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV63622765; called by muse, mutect2, varscan2
- ZGPAT | c.451A>G p.M151V | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1014505451, COSV60832633; called by muse, mutect2, varscan2
- ZNF19 | c.1090A>G p.K364E | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV55508041; called by muse, mutect2, varscan2
- ZNF423 | c.3570G>C p.E1190D (on ENST00000563137 / NM_001379286.1; = p.E1182D on NM_015069.4) | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.31); catalogued as COSV52194884; called by muse, mutect2, varscan2
- ZNF423 | c.2343C>A p.H781Q (on ENST00000563137 / NM_001379286.1; = p.H773Q on NM_015069.4) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52194907; called by muse, mutect2, varscan2
- ZNF44 | c.940A>T p.S314C (on ENST00000356109 / NM_001164276.2; = p.S266C on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV61135687; called by muse, mutect2, varscan2
- ZNF521 | c.2992C>T p.Q998* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV64128571; called by muse, mutect2, varscan2
- ZNF526 | c.342C>G p.S114R | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV56630333; called by muse, mutect2, varscan2
- ZNF536 | c.3818C>T p.S1273F | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as rs866481206, COSV62827382, COSV99052783; called by muse, mutect2, varscan2
- ZNF831 | c.2011G>C p.V671L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV64041914; called by muse, mutect2
- ZNF831 | c.4718G>T p.G1573V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as COSV64041920; called by muse, mutect2, varscan2
- ZNF91 | c.560G>C p.C187S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV56086912; called by muse, mutect2, varscan2
- ZNF98 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV100757346, COSV63335634; called by muse, mutect2
- ZSCAN1 | c.1150G>T p.V384F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as COSV56601539, COSV56605865; called by muse, mutect2
- ZSCAN5B | c.1133C>A p.T378K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62000512; called by muse, mutect2, varscan2
- ZSCAN5B | c.779G>T p.R260I | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1388499021, COSV62000518, COSV62000828; called by muse, mutect2, varscan2
- BMP10 | c.381_382del p.L128Pfs*10 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- CCKBR | c.508del p.H170Tfs*5 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- CTDSP1 | c.511del p.A171Pfs*19 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- GDF2 | c.746G>C p.R249T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- H1-8 | c.723dup p.G242Rfs*10 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | called by mutect2, pindel
- IGHV1-46 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- LILRB3 | c.526G>T p.G176W | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MAGEB6B | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- MANBA | c.544_546delinsTT p.R182Lfs*34 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | called by pindel, varscan2*
- MRC1 | c.1795G>A p.G599R | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OBI1 | c.1189dup p.C397Lfs*10 | Frame Shift Ins (INS) | VAF 17/136 reads (13%) | called by mutect2, pindel, varscan2
- OR13C4 | c.704del p.H235Pfs*11 | Frame Shift Del (DEL) | VAF 33/105 reads (31%) | called by mutect2, pindel, varscan2
- SRSF10 | c.626C>G p.S209C | Missense Mutation (SNP) | VAF 58/590 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- STARD8 | c.118del p.E40Kfs*44 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- TP53 | c.205dup p.A69Gfs*80 | Frame Shift Ins (INS) | VAF 85/192 reads (44%) | called by mutect2, pindel, varscan2
- VN1R5 | c.428A>G p.Q143R | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ABI2 | c.669C>G p.P223= (on ENST00000295851 / NM_001375719.1; = p.P217= on NM_005759.7 and 35 other RefSeq transcripts) | Silent (SNP) | VAF 44/172 reads (26%) | catalogued as rs760447848, COSV53690724, COSV53693753; called by muse, mutect2, varscan2
- ADGRL2 | c.1452G>A p.R484= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs1048814222, COSV54674441; called by muse, mutect2, varscan2
- C1orf52 | c.420A>G p.P140= | Silent (SNP) | VAF 87/247 reads (35%) | catalogued as COSV53999236; called by muse, mutect2, varscan2
- C21orf91 | c.756G>A p.V252= (on ENST00000284881 / NM_001100420.2; = p.V251= on NM_017447.4) | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV53033139; called by muse, mutect2, varscan2
- CATSPERG | c.2955G>T p.T985= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV53050087; called by muse, mutect2, varscan2
- CBLL2 | c.1053T>A p.S351= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV100081502; called by muse, mutect2, varscan2
- CD7 | c.144C>T p.C48= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99486138; called by muse, mutect2, varscan2
- CDH16 | c.1869G>T p.L623= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs1230570979, COSV100233714; called by muse, mutect2, varscan2
- CDH2 | c.2467C>A p.R823= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV52276851, COSV52285370; called by muse, mutect2, varscan2
- CNBD1 | c.651G>A p.L217= | Silent (SNP) | VAF 63/137 reads (46%) | catalogued as COSV101575277; called by muse, mutect2, varscan2
- COLEC12 | c.228C>G p.R76= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV68371734; called by muse, mutect2, varscan2
- CPA4 | c.906G>A p.K302= | Silent (SNP) | VAF 31/215 reads (14%) | catalogued as rs777535613, COSV55983908; called by muse, mutect2, varscan2
- CTSG | c.162G>T p.V54= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV53536022; called by muse, mutect2, varscan2
- DAB2 | c.393C>T p.N131= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as rs766873482, COSV57915998; called by muse, mutect2, varscan2
- DCAF12L2 | c.42C>A p.P14= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV63582747; called by muse, mutect2, varscan2
- DCSTAMP | c.204G>A p.T68= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as rs201545994, COSV52578533; called by muse, mutect2
- DMD | c.6201G>T p.T2067= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV63768269; called by muse, mutect2, varscan2
- DMD | c.4371G>A p.K1457= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as COSV63733430, COSV63768284; called by muse, mutect2, varscan2
- EIPR1 | c.645G>T p.R215= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as COSV66130943; called by muse, mutect2
- EVX2 | c.408T>A p.L136= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV57963960; called by muse, mutect2, varscan2
- FAM47B | c.1665T>A p.P555= | Silent (SNP) | VAF 48/102 reads (47%) | catalogued as COSV61454858; called by muse, mutect2, varscan2
- FBXO43 | c.786C>T p.I262= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV101413822; called by muse, mutect2, varscan2
- FLG | c.4593C>A p.S1531= | Silent (SNP) | VAF 123/513 reads (24%) | catalogued as COSV100910964; called by muse, mutect2, varscan2
- GHITM | c.360C>G p.V120= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as COSV64538766; called by muse, mutect2
- GPC3 | c.675C>A p.V225= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as COSV63666858; called by muse, mutect2, varscan2
- HEPHL1 | c.2754A>G p.R918= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as COSV59893460; called by muse, mutect2, varscan2
- IGLV3-12 | c.99A>T p.T33= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- ITGB1 | c.1158C>T p.N386= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as rs199940049, COSV56483375; called by muse, mutect2, varscan2
- JMJD1C | c.3216C>G p.R1072= | Silent (SNP) | VAF 30/245 reads (12%) | catalogued as COSV59516318; called by muse, mutect2, varscan2
- KCNB2 | c.1179A>T p.L393= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV73051128; called by muse, mutect2, varscan2
- KIF21A | c.1245G>A p.V415= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV62773853; called by muse, mutect2, varscan2
- KRTAP13-2 | c.93C>A p.P31= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV67762105; called by muse, mutect2, varscan2
- LCTL | c.873C>A p.A291= | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as COSV58422396; called by muse, mutect2, varscan2
- MAG | c.954G>T p.V318= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV62701327; called by muse, mutect2, varscan2
- MAP3K15 | c.3747G>T p.R1249= | Silent (SNP) | VAF 44/213 reads (21%) | catalogued as COSV58833109; called by muse, mutect2, varscan2
- MKI67 | c.3717A>G p.E1239= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV64075267; called by muse, mutect2
- MOV10L1 | c.1926G>T p.R642= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV53174265; called by muse, mutect2, varscan2
- MUC17 | c.1773A>C p.S591= | Silent (SNP) | VAF 24/220 reads (11%) | catalogued as COSV60293455; called by muse, mutect2, varscan2
- MUC3A | c.786A>G p.S262= | Silent (SNP) | VAF 89/203 reads (44%) | called by muse, mutect2, varscan2
- MYH1 | c.714C>A p.T238= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as COSV56851505, COSV56857475; called by muse, mutect2, varscan2
- MYH4 | c.948C>A p.V316= | Silent (SNP) | VAF 41/85 reads (48%) | catalogued as COSV55120873; called by muse, mutect2, varscan2
- NFATC3 | c.2223G>T p.L741= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV60475698; called by muse, mutect2, varscan2
- NLRC3 | c.256A>C p.R86= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV57092669; called by muse, mutect2, varscan2
- NTRK3 | c.1611C>T p.D537= | Silent (SNP) | VAF 15/127 reads (12%) | catalogued as COSV62302342; called by muse, mutect2, varscan2
- OBSCN | c.2904G>T p.R968= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV52789872; called by muse, mutect2, varscan2
- OPCML | c.1011C>A p.L337= | Silent (SNP) | VAF 32/59 reads (54%) | catalogued as COSV59415093, COSV59434691; called by muse, mutect2, varscan2
- OR1N1 | c.732C>T p.C244= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs372806915; called by muse, mutect2, varscan2
- OR2T2 | c.321C>A p.T107= | Silent (SNP) | VAF 32/192 reads (17%) | catalogued as rs1553319728, COSV61618423, COSV61619116; called by muse, mutect2, varscan2
- OSBPL8 | c.690G>A p.A230= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs201950442, COSV53881091, COSV99675557; called by muse, mutect2, varscan2
- P2RY10 | c.504C>A p.P168= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV50682485; called by muse, mutect2, varscan2
- PCDHB12 | c.1167C>T p.I389= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs267600438, COSV53398111; called by muse, mutect2, varscan2
- PITPNM1 | c.480G>T p.R160= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100039347; called by muse, mutect2, varscan2
- PRLR | c.849G>A p.L283= | Silent (SNP) | VAF 12/192 reads (6%) | catalogued as COSV99184247; called by muse, mutect2
- PRPS1L1 | c.342T>C p.N114= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV72649929; called by muse, mutect2, varscan2
- PTPN9 | c.324C>T p.S108= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV60724462; called by muse, mutect2, varscan2
- RGS1 | c.390C>A p.P130= | Silent (SNP) | VAF 75/230 reads (33%) | catalogued as COSV66505711; called by muse, mutect2, varscan2
- RP1L1 | c.813G>C p.T271= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV66756937; called by muse, mutect2, varscan2
- RSBN1L | c.939T>C p.Y313= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as COSV58509204; called by muse, mutect2, varscan2
- RYR3 | c.45G>T p.L15= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV66797194; called by muse, mutect2, varscan2
- SCML2 | c.1947C>A p.G649= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV99318690; called by muse, mutect2, varscan2
- SCN3A | c.3606T>C p.I1202= | Silent (SNP) | VAF 47/155 reads (30%) | catalogued as COSV51814727; called by muse, mutect2, varscan2
- SPANXN3 | c.90A>T p.V30= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as rs373998743, COSV65140518; called by muse, mutect2, varscan2
- SRD5A3 | c.168G>A p.K56= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV51712459; called by muse, mutect2
- STC1 | c.96C>A p.S32= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV51688981; called by muse, mutect2, varscan2
- TAF4 | c.1791A>G p.K597= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs757004601, COSV53339319; called by muse, mutect2, varscan2
- TFAP2D | c.732C>T p.L244= | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as COSV50429319; called by muse, mutect2
- TLL2 | c.414C>T p.A138= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs756774672, COSV63571449; called by muse, mutect2, varscan2
- TRIB3 | c.186G>A p.V62= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV53931837; called by muse, mutect2, varscan2
- TRIM43 | c.489A>G p.R163= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV55528634; called by muse, mutect2, varscan2
- TRIO | c.8688G>T p.L2896= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs376350332, COSV59990936; called by muse, mutect2, varscan2
- TSC22D3 | c.234G>T p.L78= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100226709; called by muse, mutect2, varscan2
- XPNPEP2 | c.1326C>G p.S442= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs747085901, COSV64369462; called by muse, mutect2, varscan2
- YTHDC2 | c.4209G>T p.G1403= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV50745057; called by muse, mutect2, varscan2
- ZBTB18 | c.1515G>A p.L505= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as COSV62397761; called by muse, mutect2, varscan2
- ZNF124 | c.936T>C p.H312= (on ENST00000543802 / NM_001297568.1; = p.H250= on NM_003431.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/126 reads (33%) | catalogued as COSV100517671; called by muse, mutect2, varscan2
- ZNF676 | c.1650G>A p.S550= (on ENST00000650058; = p.S518= on NM_001001411.3) | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs776190887, COSV68092278; called by muse, mutect2, varscan2
- ZNF688 | c.435C>T p.S145= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1176710942, COSV99794116; called by muse, mutect2
- ALMS1P1 | chr2:73700906 C>A | 3'Flank (SNP) | VAF 13/83 reads (16%) | called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73701116 G>T | 3'Flank (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- AP003393.1 | n.514+722T>C | Intron (SNP) | VAF 7/22 reads (32%) | catalogued as COSV58226962; called by muse, mutect2, varscan2
- DDIAS | c.-2A>T | 5'UTR (SNP) | VAF 28/45 reads (62%) | catalogued as COSV100231067; called by muse, mutect2, varscan2
- GRM1 | c.-1C>G | 5'UTR (SNP) | VAF 22/89 reads (25%) | catalogued as COSV99263550, COSV99264718; called by muse, mutect2, varscan2
- HUWE1 | c.1490-722G>C | Intron (SNP) | VAF 46/118 reads (39%) | called by muse, mutect2, varscan2
- IGHV1-12 | n.122G>T | RNA (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- INSIG1 | c.804+985C>T | Intron (SNP) | VAF 6/67 reads (9%) | catalogued as COSV100452891; called by muse, mutect2
- PLEKHA8P1 | n.1228G>T | RNA (SNP) | VAF 55/150 reads (37%) | called by muse, mutect2, varscan2
- POLA1 | c.2947-20949C>A | Intron (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- SNORD116-1 | n.80A>T | RNA (SNP) | VAF 19/110 reads (17%) | called by muse, mutect2, varscan2
- SSX6P | chrX:48117093 A>C | 3'Flank (SNP) | VAF 21/194 reads (11%) | catalogued as rs17327911; called by muse, mutect2, varscan2
- TTN | c.10360+3624A>G | Intron (SNP) | VAF 26/100 reads (26%) | catalogued as COSV60158103; called by muse, mutect2, varscan2
- WASF4P | n.866C>A | RNA (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- Z82195.2 | n.416-19585C>A | Intron (SNP) | VAF 19/38 reads (50%) | catalogued as rs1199269316; called by muse, mutect2, varscan2
